Somatic mutation profile of tumor specimen TARGET-30-PASNEF-01A (aliquot TARGET-30-PASNEF-01A-01D) from TARGET case TARGET-30-PASNEF, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 1.9 years (696 days).
Specimen TARGET-30-PASNEF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cd7fb22-943b-4e98-b1ab-e2658950dbe9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASNEF-10A (Blood Derived Normal), aliquot TARGET-30-PASNEF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/531412ee-ea11-4046-9a1d-c0534dee6088

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARL2 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0.305); catalogued as rs1324128674, COSV55861601; called by muse, mutect2
- CALM2 | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV55399993; called by muse, mutect2, varscan2
- GDF3 | c.472C>A p.Q158K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.96); PolyPhen benign (0.077); catalogued as COSV61713197; called by muse, mutect2, varscan2
- KIF21B | c.4843G>A p.V1615I (on ENST00000422435 / NM_001252100.2; = p.V1602I on NM_017596.4) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.311); catalogued as rs200570033, COSV59753995; called by muse, mutect2, varscan2
- MYH3 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as rs1240953921, COSV56867769; called by muse, mutect2, varscan2
- PRKCSH | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.655); catalogued as rs150738221; called by mutect2, varscan2
- SSH3 | c.983G>C p.R328P | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs372414797, COSV57385857; called by muse, mutect2, varscan2
- TCHHL1 | c.1238G>T p.R413L | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV64286680; called by muse, mutect2, varscan2
- C5 | c.1915G>T p.G639C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP17A1 | c.1194G>A p.A398= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs201222065; ClinVar: likely benign; called by muse, mutect2, varscan2
